Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3812, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3812-01A (Primary Tumor).

Diagnosis

This concerns a resected sigma sample with a moderately differentiated adenocarcinoma with histopathological differentiation grade G2, with ulceration of the inner surface of the tumor, with necrosis, with peritumoral, chronic recurrent secondary inflammation with an acute inflammation flare, with carcinomatous lymphangitis, with tumor infiltration of the sigma wall layers to the subserous fatty connective tissue, with moderate chronic lymphadenitis of the tumor-free lymph nodes (0/13), with tumor-free overview slices from the resection margins and from the anastomosis ring, as well as with a sigma diverticulosis.

According to the preparation sections at hand, the spreading of the tumor of the sigma carcinoma corresponds to a tumor stage of pT3, pN0, MX, L1, R0.

Source: NCI Genomic Data Commons file cafa497d-3987-42dc-ac87-de4d7dbd2d97 (TCGA-AA-3812.4393113D-6C83-4763-A258-96AB9B8F604D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).